Somatic mutation profile of tumor specimen C3N-02286-01 (aliquot CPT0244760006) from CPTAC case C3N-02286, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.0 years (25,581 days).
Specimen C3N-02286-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfe96dde-4eac-4d7c-aa27-2765aa39b67e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02286-31 (Blood Derived Normal), aliquot CPT0244820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a7b9190-d3e8-4a69-986e-815870f08bfc

The open-access MAF lists 101 somatic variants for this specimen: 72 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 16, Intron 7, RNA 4, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, 3'UTR 1, 3'Flank 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG1 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373885762; called by muse, mutect2, varscan2
- ADAD1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778239614, COSV56646393, COSV56646868; called by muse, mutect2, varscan2
- ANXA2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs766294564; called by muse, mutect2, varscan2
- ASPM | c.6511A>G p.K2171E | Missense Mutation (SNP) | VAF 157/421 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0.065); catalogued as rs146254857; called by muse, mutect2, varscan2
- B4GALNT2 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 63/211 reads (30%) | catalogued as rs199894921, COSV55924595; called by muse, mutect2, varscan2
- BARX2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs770581739, COSV55651198; called by muse, mutect2, varscan2
- CBFA2T3 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 127/287 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs553888710; called by muse, mutect2, varscan2
- CDH18 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759064016, COSV56914916, COSV56935577; called by muse, mutect2, varscan2
- CDH7 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59881252; called by muse, mutect2, varscan2
- ERC1 | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs571730696, COSV61693366, COSV61697937; called by muse, mutect2, varscan2
- FBXO15 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs986564490; called by muse, mutect2, varscan2
- GABRA6 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 171/445 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV50877577, COSV50900675; called by muse, mutect2, varscan2
- GOLGA6L9 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 100/458 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.957); catalogued as rs1276394087; called by mutect2, varscan2
- GRIN2A | c.1121A>T p.K374M | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.84); catalogued as COSV58054419; called by muse, mutect2, varscan2
- HYDIN | c.9224G>A p.R3075H | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs569134886, COSV59253771; called by muse, mutect2, varscan2
- KHDC3L | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 142/325 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs762594964, COSV100951108; called by muse, mutect2, varscan2
- NEUROD6 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 161/618 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV51770811, COSV51773123; called by muse, mutect2, varscan2
- PCNX1 | c.5182C>T p.R1728C | Missense Mutation (SNP) | VAF 136/339 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1318441317, COSV53090778; called by muse, mutect2, varscan2
- PIEZO2 | c.4667C>T p.T1556M | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs181523658; called by muse, mutect2, varscan2
- PLCZ1 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 103/265 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs758982697, COSV56851007; called by muse, mutect2, varscan2
- PTPRR | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150540173; called by muse, mutect2, varscan2
- RHOXF2B | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 349/435 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as rs1478039650; called by muse, mutect2, varscan2
- SLC2A1 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 232/528 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100995893; called by muse, mutect2, varscan2
- SLC6A5 | c.2023A>G p.I675V | Missense Mutation (SNP) | VAF 128/309 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as rs780454469; called by muse, mutect2, varscan2
- SSRP1 | c.1297-1G>A p.X433_splice | Splice Site (SNP) | VAF 46/101 reads (46%) | catalogued as COSV99554788; called by muse, mutect2, varscan2
- TCL1A | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV99075769; called by muse, mutect2, varscan2
- TNS2 | c.4105G>A p.V1369M (on ENST00000314250 / NM_170754.4; = p.V1379M on NM_015319.2) | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373363715; called by muse, mutect2, varscan2
- TRBV30 | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 123/359 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.495); catalogued as rs782425397; called by muse, mutect2, varscan2
- UBC | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 207/556 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV60059350; called by muse, mutect2, varscan2
- USP25 | c.1235_1237del p.T412del | In Frame Del (DEL) | VAF 21/99 reads (21%) | catalogued as rs1459708443; called by mutect2, pindel, varscan2
- VAC14 | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99935297; called by muse, mutect2, varscan2
- VRTN | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as rs138416499; called by muse, mutect2, varscan2
- ZC3H18 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 91/243 reads (37%) | catalogued as COSV56324235, COSV99964491; called by muse, mutect2, varscan2
- ZNF91 | c.2277A>C p.K759N | Missense Mutation (SNP) | VAF 129/443 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.073); catalogued as COSV100323188; called by muse, mutect2, varscan2
- ABCA4 | c.389A>C p.H130P | Missense Mutation (SNP) | VAF 241/571 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF37 | c.985del p.E330Rfs*4 | Frame Shift Del (DEL) | VAF 35/105 reads (33%) | called by mutect2, pindel, varscan2
- CARD14 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- CCNB2 | c.1100del p.K367Sfs*8 | Frame Shift Del (DEL) | VAF 45/158 reads (28%) | called by mutect2, pindel, varscan2
- CCNY | c.294C>G p.Y98* | Nonsense Mutation (SNP) | VAF 112/148 reads (76%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.4314dup p.A1439Cfs*8 | Frame Shift Ins (INS) | VAF 89/274 reads (32%) | called by mutect2, pindel, varscan2
- CDR2L | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNGA2 | c.587C>A p.T196K | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH3 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM170A | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FRAS1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GOLGA6L10 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 76/1072 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.499); called by muse, mutect2
- HHAT | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- JPH2 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 112/325 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLF11 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KMT2C | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 36/698 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- MGAM | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 16/451 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.092); called by muse, mutect2
- MINK1 | c.3366G>A p.V1122= | Splice Region (SNP) | VAF 69/117 reads (59%) | called by muse, mutect2
- MORN1 | c.477G>T p.W159C | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUSK | c.1130A>T p.H377L | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.102); called by muse, mutect2
- MYOF | c.5764G>C p.D1922H | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- NASP | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH10 | c.2713A>G p.I905V | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PKHD1 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 152/384 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.10894C>T p.P3632S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RYR1 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 238/738 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR3 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- SEMA3C | c.1998G>T p.M666I | Missense Mutation (SNP) | VAF 132/478 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKOR2 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 210/547 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLIT2 | c.2144-1G>A p.X715_splice | Splice Site (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- SMYD4 | c.380A>G p.K127R | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.129); called by muse, varscan2
- STK17B | c.391T>C p.S131P | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TAAR5 | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 130/311 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- TREH | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTN | c.30710A>T p.E10237V (on ENST00000591111; = p.E9310V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | PolyPhen benign (0.22); called by muse, mutect2, varscan2
- XKR7 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF341 | c.1985A>G p.K662R (on ENST00000375200 / NM_001282935.1; = p.K655R on NM_032819.4) | Missense Mutation (SNP) | VAF 136/500 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZRANB1 | c.32A>C p.E11A | Missense Mutation (SNP) | VAF 109/127 reads (86%) | SIFT tolerated (0.05); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ANKLE1 | c.1272C>A p.L424= (on ENST00000394458; = p.L370= on NM_152363.6) | Silent (SNP) | VAF 84/270 reads (31%) | called by muse, mutect2, varscan2
- CHRNB4 | c.657C>T p.Y219= | Silent (SNP) | VAF 62/157 reads (39%) | catalogued as rs762292972, COSV55715846; called by muse, mutect2, varscan2
- CSMD1 | c.159G>A p.P53= | Silent (SNP) | VAF 78/255 reads (31%) | catalogued as rs752200510, COSV68229497; called by muse, mutect2, varscan2
- GMPR2 | c.804A>G p.G268= (on ENST00000355299 / NM_001351022.2; = p.G286= on NM_016576.5) | Silent (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- INSYN1 | c.387G>A p.E129= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as rs1370912789; called by muse, mutect2, varscan2
- IVL | c.483G>A p.G161= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as rs12038519; called by muse, mutect2, varscan2
- MAGEB18 | c.339G>A p.S113= | Silent (SNP) | VAF 149/175 reads (85%) | catalogued as rs1305966996, COSV57464369; called by muse, mutect2, varscan2
- PCDH1 | c.2115G>A p.V705= | Silent (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- PPP1R26 | c.174G>A p.G58= | Silent (SNP) | VAF 89/184 reads (48%) | catalogued as COSV100777970, COSV63355785; called by muse, mutect2, varscan2
- SERPINB4 | c.336G>A p.T112= | Silent (SNP) | VAF 158/341 reads (46%) | catalogued as rs528469387, COSV61985088; called by muse, mutect2, varscan2
- SVIL | c.1005G>A p.A335= | Silent (SNP) | VAF 91/134 reads (68%) | catalogued as rs764204188, COSV100881515, COSV100881712; called by muse, mutect2, varscan2
- TACC3 | c.936G>A p.R312= | Silent (SNP) | VAF 123/320 reads (38%) | called by muse, mutect2, varscan2
- TMEM104 | c.531C>T p.S177= | Silent (SNP) | VAF 64/157 reads (41%) | catalogued as rs774237196, COSV100120704; called by muse, mutect2, varscan2
- TRIO | c.1269G>A p.A423= | Silent (SNP) | VAF 112/275 reads (41%) | catalogued as rs377545795; called by muse, mutect2, varscan2
- TTN | c.90375C>T p.S30125= (on ENST00000591111; = p.S22701= on NM_003319.4) | Silent (SNP) | VAF 77/240 reads (32%) | called by muse, mutect2, varscan2
- ZNF311 | c.1125C>G p.T375= | Silent (SNP) | VAF 16/289 reads (6%) | called by muse, mutect2
- ABCB11 | c.1639-114C>T | Intron (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- ABCB4 | chr7:87401924 A>G | 3'Flank (SNP) | VAF 41/185 reads (22%) | called by muse, mutect2, varscan2
- B3GALNT2 | c.*1581C>T | 3'UTR (SNP) | VAF 97/238 reads (41%) | called by muse, mutect2, varscan2
- BAGE2 | n.199C>A | RNA (SNP) | VAF 45/559 reads (8%) | called by muse, mutect2
- EYS | c.1767-7862T>C | Intron (SNP) | VAF 81/287 reads (28%) | called by muse, mutect2, varscan2
- LAMA1 | c.1156-34A>T | Intron (SNP) | VAF 72/172 reads (42%) | called by muse, mutect2, varscan2
- LRP1 | c.67+13C>T | Intron (SNP) | VAF 83/219 reads (38%) | called by muse, mutect2, varscan2
- NANOGP1 | n.573C>A | RNA (SNP) | VAF 7/38 reads (18%) | catalogued as rs773052557; called by mutect2, varscan2
- NOC2LP2 | n.1896C>T | RNA (SNP) | VAF 71/186 reads (38%) | catalogued as rs534438859; called by muse, mutect2, varscan2
- NR2C1 | c.1393+495C>G | Intron (SNP) | VAF 68/182 reads (37%) | called by muse, mutect2, varscan2
- PTPN4 | c.1656+17_1656+18insC | Intron (INS) | VAF 52/130 reads (40%) | called by mutect2, pindel*, varscan2
- SSPOP | n.2969C>T | RNA (SNP) | VAF 138/480 reads (29%) | catalogued as rs374198119; called by muse, varscan2
- TUBB3 | c.277+29G>A | Intron (SNP) | VAF 179/415 reads (43%) | called by muse, mutect2, varscan2
